Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A2I6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A2I6-01A (Primary Tumor).

[page 1 of 6]
PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service: Urology

Billing

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

male with primary T2 high grade TCC involving right hemitrigone with right hydronephrosis.

Specimens Submitted:

- 1: SP: Bladder, seminal vesicle, prostate and perivesical nodes, radical cystoprostatectomy
- 2: SP: Vas deferens, right, resection
- 3: SP: Vas deferens, left, resection
- 4: SP: Lymph nodes, left pelvic, excision
- 5: SP: Lymph nodes, right pelvic, excision
- 6: SP: Fat, anterior prostate, resection
- 7: SP: Soft tissue, left anterior abdominal wall, resection
- 8: SP: Ureter, left, excision
- 9: SP: Ureter, right, excision

DIAGNOSIS:

1. SP: Bladder, seminal vesicle, prostate and perivesical nodes, radical cystoprostatectomy

a.

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Deep half of muscularis propria

Extravesical Tumor Extension:

The right ureter shows focal marked atypia at the margin of resection.

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

The right ureter shows focal marked atypia at the margin of resection.

1CD-0-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, trigone C67.0
lw
6/24/14

ICD-9 Discrepancy		

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Non-Neoplastic Mucosa:

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

Prostate:

Other See separate form

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

LN Not involved 0/1

The Pathologic Stage is (AJCC 2002):

pT2b (Invades deep half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:4

Total Gleason score:7

Tumor Location:

Involves Right anterior

Involves Left posterior

Involves Left anterior

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Not Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Unremarkable

Staging (AJCC 1997):

pT2b (confined to the prostate & capsule, involving both lobes)

2. SP: Vas deferens, right, resection

Segment of benign vas deferens.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

3. **SP: Vas deferens, left, resection**
Segment of benign vas deferens.
4. **SP: Lymph nodes, left pelvic, excision**
Lymph Nodes:
Number of nodes examined:8
Number of metastatic nodes:0
-
5. **SP: Lymph nodes, right pelvic, excision**
Lymph Nodes:
Number of nodes examined:21
Number of metastatic nodes:1
The largest metastatic node is 0.7cm
Perinodal (extracapsular) extension not identified
-
6. **SP: Fat, anterior prostate, resection**
One benign lymph node(0/1).
7. **SP: Soft tissue, left anterior abdominal wall, resection**
Benign adipose tissue.
8. **SP: Ureter, left, excision,**
Segment of benign ureter.
9. **SP: Ureter, right, excision**
Segment of benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Bladder, Seminal Vesicle, Prostate and Perivesical Nodes". It consists of a bladder measuring 9.5 x 8 x 2 cm and a prostate measuring 5 x 3 x 2.5 cm. Overall the specimen measures 23 x 15 x 3.8 cm. The bladder is opened anteriorly to reveal a round, firm, exophytic mass on the right aspect of the trigone measuring 3 x 2 x 1 cm. The rest of the mucosa is markedly edematous showing prominent trabeculation. The tumor is compressing on the right ureteral orifice and the right ureter is markedly dilated (0.4 cm). Sectioning of the tumor reveals a gray-tan, homogeneous, firm, well-delineated cut surface. Grossly, the tumor does not infiltrate through the muscular wall and measures 1.8 cm in maximum thickness. Sectioning the prostate reveals no gross pathologic abnormalities. Representative sections are submitted. The perivesical fat is dissected in searched for perivesical lymph nodes which are not seen grossly. Tissue is submitted for TPS. Photographs are taken.

Summary of Sections:

UM – urethral margin
URM – ureteral margin (green ink on right ureter)
T – tumor
TR – trigone
LUO – left ureteral orifice
PW – posterior wall
AW – anterior wall
RW – right wall
LW – left wall

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

DO – dome
AA – anterior apex, (first block from the right)
AP – posterior apex
AM - anterior mid
PM - posterior mid portion of the prostate
AB – anterior base
PB – psoterior base
RSV – right seminal vesicle
LSV – left seminal vesicle
PVLN - perivesical lymph nodes
PA – posterior apex

2) The specimen is received in formalin, labeled "Right Vas Deferens". It consists of a vas deferens measuring 2 cm in length and 0.2 cm in diameter. The specimen is entirely submitted.

Summary of Sections:
U - undesignated

3) The specimen is received in formalin, labeled "Left Vas Deferens". It consists of a vas deferens measuring 1.7 cm in length and 0.2 cm in diameter. The specimen is entirely submitted.

Summary of Sections:
U - undesignated

4) The specimen is received in formalin, labeled "Left Pelvic Lymph Nodes". It consists of an irregular fragment of adipose tissue measuring 6 x 3.5 x 1 cm in aggregate. Multiple lymph nodes are identified. The specimen is entirely submitted.

Summary of Sections:
BLN - bisected lymph node
MLN – multiple lymph nodes

5) The specimen is received in formalin, labeled "Right Pelvic Lymph Nodes". It consists of multiple fragments of yellow-tan adipose tissue measuring 3.5 x 5 x 1.8 cm in aggregate. Multiple lymph nodes are dissected ranging in size from 0.2 x 0.2 x 0.1 cm to 2 x 1 x 0.7 cm. The largest lymph node is bisected. All lymph nodes are submitted.

Summary of Sections:
BLN - bisected lymph node
LN - lymph nodes

6) The specimen is received in formalin, labeled "Anterior Prostate Fat". It consists of a fragment of yellow-tan adipose tissue measuring 3 x 2 x 1 cm. Presumably one lymph node is dissected measuring 0.4 x 0.4 x 0.2 cm. The lymph node and the remaining tissue are entirely submitted.

Summary of Sections:
LN - lymph nodes
U - undesignated

7) The specimen is received in formalin, labeled "Left Anterior Abdominal Wall Fat". It consists of two fragments of adipose tissue measuring 3 x 2.5 x 0.7 cm in aggregate. Sectioning through the tissue reveals no gross pathologic abnormalities. The specimen is entirely submitted.

Summary of Sections:

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

U - undesignated

8) The specimen is received in formalin, labeled "Left Ureter (clip on the most distal end)". It consists of a piece of pink-tan and white-tan tissue measuring 1.5 x 1 x 0.8 cm. One side of the tissue is oriented with a clip at the distal end of the ureter. Sectioning of the tissue reveals a white-tan, tube-like structure that grossly shows no significant pathologic abnormalities. The specimen is entirely submitted.

Summary of Sections:

DE - distal end of ureter

PE - proximal end of ureter

M - mid portion of the tissue

9) The specimen is received in formalin, labeled "Right Ureter". It consists of a ureter with surrounding adipose tissue with clip on distal end, measuring 2 cm in length and 0.4 cm in diameter. The specimen is entirely submitted.

Summary of Sections:

DM - distal margin

PM - proximal margin

SS - serially sectioned ureter

Summary of Sections:

Part 1: SP: Bladder, seminal vesicle, prostate and perivesical nodes, radical cystoprostatectomy

Block	Sect. Site	PCs
2	ab	2
2	am	2
2	ap	2
1	aw	1
1	do	1
1	lsv	1
1	luo	1
1	lw	1
2	pa	2
2	pb	2
2	pm	2
1	pvl	1
1	pw	1
1	rsv	1
1	rw	1
4	t	4
1	tr	1
1	um	1
1	urm	1

Part 2: SP: Vas deferens, right, resection (tl)

Block	Sect. Site	PCs
2	u	7

Part 3: SP: Vas deferens, left, resection (tl)

Block	Sect. Site	PCs
2	u	5

Part 4: SP: Lymph nodes, left pelvic, excision (tl)

Block	Sect. Site	PCs
3	bln	6

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1 mln 4

Part 5: SP: Lymph nodes, right pelvic, excision

Block	Sect. Site	PCs
1	bln	1
6	ln	6

Part 6: SP: Fat, anterior prostate, resection (tl)

Block	Sect. Site	PCs
1	ln	1
1	u	1

Part 7: SP: Soft tissue, left anterior abdominal wall, resection

Block	Sect. Site	PCs
2	u	2

Part 8: SP: Ureter, left, excision,

Block	Sect. Site	PCs
1	de	1
1	m	1
1	pe	1

Part 9: SP: Ureter, right, excision

Block	Sect. Site	PCs
1	dm	1
1	pm	1
1	ss	3

Source: NCI Genomic Data Commons file 99b040db-b0ea-4783-939a-2e2e2d7e2a4b (TCGA-DK-A2I6.4CDD4632-B977-4B97-BAE5-8442F1D9319A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).